Somatic mutation profile of tumor specimen MBCProject_1408_T1_WES (aliquot MBCProject_1408_T1_WES_1) from CMI case MBCProject_1408, project CMI-MBC: Count Me In (CMI): The Metastatic Breast Cancer (MBC) Project. Sex at birth: female; Primary diagnosis: Infiltrating lobular carcinoma, NOS; Tissue or organ of origin: Breast, NOS; Age at diagnosis: 52.8 years (19,268 days).
Specimen MBCProject_1408_T1_WES: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Breast; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 16feb11f-5309-46f8-8961-42278515cf22.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MBCProject_1408_SALIVA (Saliva), aliquot MBCProject_1408_SALIVA_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/de1cd5ab-6c14-48a4-8d21-d0453f8090b3

The open-access MAF lists 4 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 2, 5'Flank 1, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- VWF | c.7432C>T p.R2478W | Missense Mutation (SNP) | VAF 5/7 reads (71%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.659); catalogued as rs771694902, COSV54614623; called by muse, mutect2
- ZNF41 | c.1105G>A p.D369N | Missense Mutation (SNP) | VAF 8/10 reads (80%) | SIFT tolerated (0.25); PolyPhen benign (0); called by mutect2, varscan2
- DYNC1H1 | c.4827A>T p.G1609= | Silent (SNP) | VAF 20/22 reads (91%) | called by mutect2, varscan2
- AP000769.5 | chr11:65501095 T>G | 5'Flank (SNP) | VAF 16/16 reads (100%) | called by mutect2, varscan2
